Somatic mutation profile of tumor specimen TCGA-CC-A8HU-01A (aliquot TCGA-CC-A8HU-01A-11D-A35Z-10) from TCGA case TCGA-CC-A8HU, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 39.3 years (14,367 days).
Specimen TCGA-CC-A8HU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b254e278-8062-4f9e-8aa4-7698b9d8616c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CC-A8HU-10A (Blood Derived Normal), aliquot TCGA-CC-A8HU-10A-01D-A35Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12b805a5-c237-44a4-9754-3fd0d585469e

The open-access MAF lists 101 somatic variants for this specimen: 73 protein-altering or splice-affecting, 24 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 24, Nonsense Mutation 6, In Frame Del 2, Frame Shift Del 2, Intron 2, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 34/44 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ABCG4 | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 29/33 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100267058; called by muse, mutect2, varscan2
- ACTN2 | c.2618G>A p.G873D | Missense Mutation (SNP) | VAF 97/165 reads (59%) | SIFT tolerated (0.96); PolyPhen benign (0.03); catalogued as COSV100857053; called by muse, mutect2, varscan2
- AJM1 | c.886G>T p.A296S | Missense Mutation (SNP) | VAF 46/50 reads (92%) | SIFT tolerated (0.83); PolyPhen benign (0.01); catalogued as rs1415228809, COSV56032523, COSV99915909; called by muse, mutect2, varscan2
- AMY1C | c.1003C>A p.L335M | Missense Mutation (SNP) | VAF 102/680 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.208); catalogued as rs778192509, COSV100915244; called by muse, mutect2, varscan2
- AR | c.563C>A p.A188D | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); catalogued as COSV101019602; called by muse, mutect2, varscan2
- ASAP3 | c.1331G>T p.C444F | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1289039830, COSV100369701; called by muse, mutect2, varscan2
- ATP1A2 | c.1651G>T p.G551* | Nonsense Mutation (SNP) | VAF 21/86 reads (24%) | catalogued as COSV100768177; called by muse, mutect2, varscan2
- BCHE | c.1651A>G p.T551A | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100013015; called by muse, mutect2, varscan2
- BMPER | c.47G>T p.R16L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs866309179, COSV99780621; called by muse, mutect2, varscan2
- CDH4 | c.206A>G p.Q69R | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs182629710, COSV100849724; called by muse, mutect2, varscan2
- CR2 | c.2722A>G p.K908E | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.047); catalogued as COSV100889710; called by muse, mutect2, varscan2
- CSMD1 | c.9854C>G p.A3285G (on ENST00000520002; = p.A3284G on NM_033225.6) | Missense Mutation (SNP) | VAF 40/49 reads (82%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV100154046; called by muse, mutect2, varscan2
- CXorf58 | c.44C>G p.S15* | Nonsense Mutation (SNP) | VAF 204/374 reads (55%) | catalogued as COSV101003112; called by muse, mutect2
- DHX57 | c.3317_3319del p.E1106del | In Frame Del (DEL) | VAF 44/126 reads (35%) | catalogued as rs770136975; called by pindel, varscan2
- DNAH11 | c.4861A>T p.K1621* | Nonsense Mutation (SNP) | VAF 91/180 reads (51%) | catalogued as COSV100181011; called by muse, mutect2, varscan2
- DNAH17 | c.4294C>A p.P1432T | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV67758207; called by muse, mutect2, varscan2
- EEF1AKMT1 | c.407A>T p.D136V | Missense Mutation (SNP) | VAF 42/1059 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776773528, COSV101236956; called by muse, mutect2
- ELMOD1 | c.780C>G p.F260L | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT tolerated (0.84); PolyPhen benign (0.052); catalogued as COSV56193456, COSV99760445; called by muse, mutect2, varscan2
- EXO1 | c.2483A>G p.E828G | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.7); catalogued as rs1001293843, COSV100800205, COSV62218081; called by muse, mutect2, varscan2
- FAT3 | c.6667A>T p.I2223F | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.268); catalogued as COSV99971392; called by muse, mutect2, varscan2
- FCGBP | c.7615C>A p.L2539M | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV99664233; called by muse, mutect2
- GGTLC1 | c.467A>G p.E156G | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV99600951; called by muse, mutect2, varscan2
- HACD1 | c.754C>A p.L252I | Missense Mutation (SNP) | VAF 153/469 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV63516489; called by muse, mutect2, varscan2
- INAVA | c.862T>G p.S288A | Missense Mutation (SNP) | VAF 44/340 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV100950131; called by muse, mutect2, varscan2
- ISL2 | c.673G>T p.V225L | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.582); catalogued as COSV99320888; called by muse, mutect2, varscan2
- IWS1 | c.1522G>C p.A508P | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as COSV99767535; called by muse, mutect2, varscan2
- KIF6 | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 58/99 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54696365; called by muse, mutect2, varscan2
- KRTAP5-10 | c.410G>T p.C137F | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.118); catalogued as COSV100924169; called by muse, mutect2, varscan2
- KY | c.363C>A p.N121K | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV101415040; called by muse, mutect2, varscan2
- LARGE2 | c.1870C>T p.R624* | Nonsense Mutation (SNP) | VAF 44/76 reads (58%) | catalogued as rs745786336, COSV99138536; called by muse, mutect2, varscan2
- LIG3 | c.1427C>T p.S476L | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as rs761685440, COSV52005472; called by muse, mutect2, varscan2
- MAGED1 | c.385T>C p.S129P | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.081); catalogued as COSV100431832; called by muse, mutect2, varscan2
- MED12 | c.5068C>G p.L1690V | Missense Mutation (SNP) | VAF 178/317 reads (56%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as COSV100380085, COSV61334677; called by muse, varscan2
- METTL21C | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.11); catalogued as COSV99940149; called by muse, mutect2, varscan2
- MSL3 | c.1393G>A p.E465K (on ENST00000312196 / NM_078629.4; = p.E299K on NM_006800.4) | Missense Mutation (SNP) | VAF 115/192 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100385080; called by muse, mutect2, varscan2
- N4BP3 | c.1253A>G p.E418G | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV99200833; called by muse, mutect2, varscan2
- NIBAN1 | c.2201C>A p.T734K | Missense Mutation (SNP) | VAF 49/77 reads (64%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.022); catalogued as COSV100836639; called by muse, mutect2, varscan2
- NT5DC1 | c.122T>G p.L41R | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100127300; called by muse, mutect2, varscan2
- NYNRIN | c.4040C>T p.P1347L | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV66841149; called by muse, mutect2, varscan2
- OR2G6 | c.269A>T p.K90I | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100598333, COSV58575115; called by muse, mutect2, varscan2
- P3H1 | c.2011G>A p.A671T | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99355620; called by muse, mutect2, varscan2
- PAPPA2 | c.4873G>A p.E1625K | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0.065); catalogued as rs1468371812, COSV100868698; called by muse, mutect2, varscan2
- PCNX3 | c.5200G>T p.V1734L | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV100856659; called by muse, mutect2, varscan2
- PER2 | c.421G>T p.A141S | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99612613; called by muse, mutect2, varscan2
- PLCE1 | c.5831A>G p.N1944S | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.988); catalogued as rs1344794553, COSV53377237; called by muse, mutect2, varscan2
- PLEKHH2 | c.2176G>A p.V726I | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.836); catalogued as COSV99030770, COSV99175126; called by muse, mutect2, varscan2
- PLXNA4 | c.4475G>A p.R1492H | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58103431; called by muse, mutect2, varscan2
- PLXNC1 | c.4126C>T p.P1376S | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV99313901; called by muse, mutect2, varscan2
- PNO1 | c.608T>C p.V203A | Missense Mutation (SNP) | VAF 49/292 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99721615; called by muse, mutect2, varscan2
- POFUT1 | c.838A>G p.M280V | Missense Mutation (SNP) | VAF 5/120 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.021); catalogued as COSV101003382; called by muse, mutect2
- PRSS57 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 58/145 reads (40%) | catalogued as rs376121318; called by muse, mutect2, varscan2
- RB1 | c.197T>A p.I66K | Missense Mutation (SNP) | VAF 38/52 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV99926930; called by muse, mutect2
- RB1 | c.199C>G p.P67A | Missense Mutation (SNP) | VAF 40/52 reads (77%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99926931; called by muse, mutect2
- RBM17 | c.851A>G p.E284G | Missense Mutation (SNP) | VAF 71/181 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as COSV101159181; called by muse, mutect2, varscan2
- RHOBTB1 | c.571T>C p.F191L | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.046); catalogued as COSV100558700; called by muse, mutect2, varscan2
- SEM1 | c.152A>T p.D51V | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99949647; called by muse, mutect2, varscan2
- SEZ6L | c.1416C>G p.N472K | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as COSV99962995; called by muse, mutect2, varscan2
- SLC5A12 | c.401A>G p.Q134R | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as COSV54824190, COSV99745552; called by muse, mutect2, varscan2
- SND1 | c.966G>T p.R322S | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV100691178; called by muse, mutect2, varscan2
- SREBF2 | c.1496C>G p.S499C | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV100761539, COSV100761560; called by muse, mutect2, varscan2
- STYXL2 | c.2539C>T p.L847F | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV99609929; called by muse, mutect2, varscan2
- TDRD5 | c.778A>T p.K260* | Nonsense Mutation (SNP) | VAF 101/336 reads (30%) | catalogued as COSV99677239; called by muse, mutect2, varscan2
- TMEM74 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.359); catalogued as COSV52465139, COSV99865948; called by muse, mutect2
- TPGS2 | c.280G>T p.A94S | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.112); catalogued as COSV100528923; called by muse, mutect2, varscan2
- TRIM25 | c.729A>C p.Q243H | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV100381170; called by muse, mutect2, varscan2
- TTYH2 | c.257C>A p.S86Y | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.905); catalogued as COSV99483226; called by muse, mutect2, varscan2
- ZER1 | c.927T>G p.I309M | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.201); catalogued as COSV99402432; called by muse, mutect2
- ZNF20 | c.364A>G p.T122A | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV100503175; called by muse, mutect2, varscan2
- ACVR2A | c.1419_1435del p.C474Yfs*26 | Frame Shift Del (DEL) | VAF 26/65 reads (40%) | called by mutect2, pindel, varscan2
- IGKV1-27 | c.196C>A p.P66T | Missense Mutation (SNP) | VAF 72/144 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ITGB5 | c.2267del p.K756Sfs*76 | Frame Shift Del (DEL) | VAF 18/62 reads (29%) | called by mutect2, pindel, varscan2
- LRRC49 | c.1676_1678del p.R559del | In Frame Del (DEL) | VAF 25/61 reads (41%) | called by mutect2, pindel, varscan2
- AR | c.564C>A p.A188= | Silent (SNP) | VAF 50/160 reads (31%) | catalogued as COSV101019604; called by muse, mutect2, varscan2
- C2orf16 | c.4680C>T p.N1560= | Silent (SNP) | VAF 40/78 reads (51%) | catalogued as COSV100820913, COSV100821039; called by muse, mutect2, varscan2
- CFAP65 | c.3834C>A p.G1278= | Silent (SNP) | VAF 84/170 reads (49%) | catalogued as COSV100445965; called by mutect2, varscan2
- DIP2A | c.3495G>T p.V1165= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV59488293; called by muse, mutect2, varscan2
- DYNC1H1 | c.4215C>T p.S1405= | Silent (SNP) | VAF 42/76 reads (55%) | catalogued as rs748713162, COSV100795439; ClinVar: likely benign; called by muse, mutect2, varscan2
- EIF4E | c.84T>G p.V28= | Silent (SNP) | VAF 37/45 reads (82%) | catalogued as COSV99794979; called by muse, mutect2, varscan2
- ELOA | c.1785G>A p.V595= | Silent (SNP) | VAF 32/99 reads (32%) | catalogued as COSV101403847; called by muse, mutect2, varscan2
- FUCA1 | c.777G>T p.V259= | Silent (SNP) | VAF 32/61 reads (52%) | catalogued as COSV100992210; called by muse, mutect2, varscan2
- GNAS | c.966C>T p.P322= | Silent (SNP) | VAF 97/183 reads (53%) | catalogued as rs762117523, COSV100006247, COSV58347166; called by muse, mutect2, varscan2
- GUCY1A2 | c.939T>A p.P313= | Silent (SNP) | VAF 47/58 reads (81%) | catalogued as COSV99977053; called by muse, mutect2, varscan2
- IGSF9B | c.2073G>A p.Q691= | Silent (SNP) | VAF 12/14 reads (86%) | catalogued as COSV100318476; called by muse, mutect2, varscan2
- KCNK17 | c.549C>A p.G183= | Silent (SNP) | VAF 57/108 reads (53%) | catalogued as COSV100950305; called by muse, mutect2, varscan2
- KLHL35 | c.915C>A p.I305= | Silent (SNP) | VAF 15/17 reads (88%) | catalogued as COSV100888781, COSV100888795; called by muse, mutect2, varscan2
- KRTAP4-4 | c.360C>T p.C120= | Silent (SNP) | VAF 43/90 reads (48%) | catalogued as COSV101180580; called by muse, mutect2, varscan2
- PAQR6 | c.786C>A p.I262= (on ENST00000292291 / NM_001272108.2; = p.S180Y on NM_024897.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV99431650; called by muse, mutect2, varscan2
- PCDHB6 | c.48C>T p.F16= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs143226291; called by muse, mutect2, varscan2
- PHF8 | c.2025C>T p.P675= (on ENST00000357988 / NM_001184896.1; = p.P639= on NM_015107.3) | Silent (SNP) | VAF 83/146 reads (57%) | catalogued as COSV100154908; called by muse, mutect2, varscan2
- POTEH | c.6G>T p.V2= | Silent (SNP) | VAF 101/436 reads (23%) | catalogued as COSV100625270; called by muse, mutect2, varscan2
- RPS16 | c.21G>T p.L7= | Silent (SNP) | VAF 29/42 reads (69%) | catalogued as COSV99261913; called by muse, mutect2
- SYDE1 | c.2103C>T p.D701= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV99655147; called by muse, mutect2, varscan2
- TAF1 | c.1002T>A p.G334= (on ENST00000373790 / NM_138923.4; = p.G355= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/210 reads (25%) | catalogued as COSV99337067; called by muse, mutect2, varscan2
- TINF2 | c.240G>A p.L80= | Silent (SNP) | VAF 42/103 reads (41%) | catalogued as rs145115622, COSV57468913; called by muse, mutect2, varscan2
- TRIOBP | c.3768G>A p.A1256= | Silent (SNP) | VAF 38/72 reads (53%) | catalogued as rs756831977, COSV60375701; called by muse, mutect2, varscan2
- UBR4 | c.8958T>G p.P2986= | Silent (SNP) | VAF 35/121 reads (29%) | catalogued as COSV100921957; called by muse, mutect2, varscan2
- LEKR1 | c.*640C>A | 3'UTR (SNP) | VAF 10/29 reads (34%) | catalogued as COSV100739353; called by muse, mutect2, varscan2
- MIR181A1 | n.33C>T | RNA (SNP) | VAF 65/121 reads (54%) | catalogued as rs868055902; called by muse, mutect2, varscan2
- NAA38 | c.82-82C>G | Intron (SNP) | VAF 26/32 reads (81%) | catalogued as COSV99642373; called by muse, mutect2, varscan2
- SKA2 | c.34-6423G>A | Intron (SNP) | VAF 42/132 reads (32%) | catalogued as COSV100350263; called by muse, mutect2, varscan2
